Surgical pathology report (de-identified scan), TCGA case TCGA-46-3766, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site St. Joseph's Medical Center (MD), specimen TCGA-46-3766-01A (Primary Tumor).

[page 1 of 3]
SPEC #: [REDACTED] RECD: [REDACTED] STATUS: [REDACTED]
COLL: [REDACTED] SUBM DR: [REDACTED]
ENTERED: [REDACTED] SP TYPE: SURGICAL P OTHR DR: [REDACTED]
ORDERED: 88305, 88307/2, 88313, 88331, LEVEL IV - GROS, LEVEL V - GROSS/2, SPECIA
PATHOLOGY CONSU

PRIORITY: FROZEN SEC

SURGICAL PROCEDURES:
LUNG-LOBECTOMY, REGIONAL LYMPH

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "right lower lobe lung wedge" and consists of a wedge-shaped segment of lung measuring 7 x 2 x 2 cm. The pleural surface is pink tan to gray tan and reticulated with deposits of black carbon pigment interrupted by a ragged approximate 1 cm pleural area which will be marked with black dye. Sectioning reveals a tan lesion measuring 1 cm in dimension, approaching 0.7 cm of the stapled margin directly underlying the pleura. The staple line is removed and the surgical margin marked with blue dye. Representative sections are submitted, 4 (2) labeled "1" and "2"; and 1 (1) labeled [REDACTED] used for frozen section.

FROZEN SECTION DIAGNOSIS: Non-small cell ca which appears to be involving a central bronchus; favor primary squamous carcinoma. [REDACTED]

B. The specimen is submitted fresh as "anterior interlobar node" and consists of four gray black nodular segments of tissue ranging 0.6 cm to 1.6 cm in dimension. Bisection of the largest is unremarkable. The specimen is submitted in toto, 5 (1), the three smaller intact, the largest bisected.

C. The specimen is submitted fresh as "right lower lobe" and consists of a lobe of lung measuring 12.5 x 8 x 5 cm, weighing 179 grams. The pleural surface is purple tan and reticulated with deposits of black carbon pigment interrupted by two linear stapled margins measuring 3 and 4.5 cm in dimension. A defined stapled bronchial margin is seen measuring 1.3 cm in diameter. Three defined vascular margins are noted sealed with metallic staples ranging from 0.6 cm to 1 cm in dimension. A single defined node is seen at the hilum measuring 0.9 cm in diameter. Bisection of the node is unremarkable. Dissection of the bronchial tree is

Patient: [REDACTED]

Age/Sex: [REDACTED]

[page 2 of 3]
GROSS DESCRIPTION

(Continued)

unremarkable. Serial sectioning reveals a combination of air-filled spongy tissue and dense airless tissue. A defined lesion is not seen. Representative sections are submitted, 15 (8) labeled "1" through "8" including:

Cassette 1: Bronchial margin
Cassette 2: Vessel margin
Cassette 3: Bisected single node
Cassettes 4-8: Representative sections of pulmonary parenchyma

FINAL DIAGNOSIS

- A. LUNG, RIGHT LOWER LOBE (WEDGE RESECTION):
- MODERATELY TO POORLY DIFFERENTIATED SQUAMOUS CARCINOMA.
- TUMOR MEASURES 1 CM IN MAXIMUM DIMENSION AND APPEARS TO ARISE FROM BRONCHIAL MUCOSA.
- TUMOR DOES NOT DIRECTLY PENETRATE THE VISCERAL PLEURA (ELASTIN) AND IS 0.7 CM FROM STAPLED PARENCHYMAL MARGIN GROSSLY, 0.2 CM FROM INKED PARENCHYMAL MARGIN AFTER STAPLES ARE REMOVED.
- FOR FINAL NEGATIVE BRONCHIAL MARGIN SEE PART "C".
- LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- NON-NEOPLASTIC PARENCHYMA SHOWS EMPHYSEMATOUS CHANGE NEARING HONEYCOMB LUNG.
- B. LYMPH NODE, ANTERIOR INTERLOBAR: FOUR ANTHRACOTIC LYMPH NODES, NEGATIVE FOR TUMOR.
- C. RIGHT LOWER LOBE (LOBECTOMY): BENIGN LUNG PARENCHYMA WITH EMPHYSEMATOUS CHANGE, CONSOLIDATION, FOCAL INTERSTITIAL FIBROSIS, AND FRESH HEMORRHAGE. BRONCHIAL AND VASCULAR MARGINS ARE NEGATIVE FOR TUMOR. ONE PERIBRONCHIAL LYMPH NODE NEGATIVE FOR TUMOR.

PATHOLOGIC STAGE: pT1 NO MX

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY
LATERALITY: RIGHT
TUMOR SITE: RIGHT LOWER LOBE
TUMOR SIZE: 1 CM
HISTOLOGIC TYPE: SQUAMOUS
HISTOLOGIC GRADE: 2-3

Patient:

Age/Sex:

[page 3 of 3]
SYNOPTIC REPORT

(Continued)

EXTENT OF INVASION: CONFINED TO LUNG
EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): NONE
ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC: (SEE
NARRATIVE)

MARGINS:

BRONCHIAL: UNINVOLVED
PARENCHYMAL: UNINVOLVED
VASCULAR: UNINVOLVED
DISTANCE TO PERTINENT MARGIN(S) (AS APPLICABLE): 0.1 CM TO PLEURAL
SURFACE

VENOUS INVASION: ABSENT
ARTERIAL (LARGE VESSEL) INVASION: ABSENT

LYMPH NODE:

f, , , , N1 - # INVOLVED/# EXAMINED: 0/MULTIPLE
f, , , , N2 - # INVOLVED/#EXAMINED: 0/MULTIPLE
f, , , , N3 - # INVOLVED/# EXAMINED: N/A

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

pTNM STAGE: pT1 N0 MX

Signed (Electronically) < SIGNATURE ON FILE >

PATHOLOGIST

atient:

Age/Sex:

Source: NCI Genomic Data Commons file 40d6b7a9-b39a-4c8e-910d-c490423672e1 (TCGA-46-3766.188FD38F-839C-49EC-B8E6-41655C2A8479.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).